Somatic mutation profile of tumor specimen 0DENCL from CCDI case PBBPUG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.2 years (806 days).
Specimen 0DENCL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5dbf6fd5-f8e3-4200-ad53-905787fab5a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DENBT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/877a64da-f367-431c-8d89-c966bf43dd8e

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELP1 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 123/607 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375957332; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIRREL3 | c.1934A>G p.E645G | Missense Mutation (SNP) | VAF 346/665 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CD300LF | c.516C>T p.A172= | Silent (SNP) | VAF 223/602 reads (37%) | catalogued as rs111797936; called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
